Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23Y, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23Y-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

OK - per 4/21/11 lw.

....

Clinical Diagnosis & History:

y/o male with pelvic mass suspicious for sarcoma.

Specimens Submitted:

- 1: SP: Biopsy of retroperitoneal mass
- 2: SP: Retroperitoneal sarcoma
- 3: SP: Left colon
- 4: SP: Retroperitoneal sarcoma
- 5: SP: Appendix

ICD-0-3

Dedifferentiated liposarcoma
8858/3

Site: retroperitoneum C48.0

lw 4/21/11

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEAL MASS; BIOPSY:
- HIGH GRADE SPINDLE SARCOMA (SEE PART #2 AND 4).
- 2) SOFT TISSUE, RETROPERITONEAL MASS; EXCISION:
- HIGH GRADE SPINDLE AND PLEOMORPHIC SARCOMA MOST CONSISTENT WITH A DEDIFFERENTIATED LIPOSARCOMA (SEE PART # 4).
- TUMOR MEASURES 20 X 18 X 10 CM.
- TUMOR INVOLVES FIBROADIPOSE TISSUE AND SUBSEROUSAL ADIPOSE TISSUE OF BOWEL SEGMENTS.
- TUMOR EXTENDS TO INKED SURGICAL MARGINS. BOWEL MARGINS NEGATIVE.
- LARGE AREAS OF NECROSIS IDENTIFIED (20% GROSS ESTIMATE).
- NO OBVIOUS AREAS OF WELL-DIFFERENTIATED LIPOSARCOMA IDENTIFIED IN THIS GENEROUSLY SAMPLED SPECIMEN, HOWEVER, THIS FINDING WAS PRESENT IN PART#4, SUPPORTING THE DIAGNOSIS OF A DEDIFFERENTIATED LIPOSARCOMA.
- 3) LEFT COLON; PARTIAL COLECTOMY:
- MICROSCOPIC FOCUS OF HIGH GRADE SPINDLE CELL SARCOMA (0.3 CM) INVOLVING PERICOLONIC ADIPOSE TISSUE.
- ACUTE SEROSITIS.
- UNREMARKABLE BOWEL WALL.
- BENIGN LYMPHANGIOMA IN PERICOLONIC FAT.
- ONE BENIGN LYMPH NODE (0/1).
- 4) SOFT TISSUE, RETROPERITONEUM; EXCISION:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA WITH A SMALL COMPONENT OF WELL-DIFFERENTIATED

** Continued on next page **

[page 2 of 5]
LIPOSARCOMA, SCLEROSING AND LIPOMA-LIKE.

- THE HIGH GRADE COMPONENT SHOWS A HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE PATTERN.

- BOTH LOW AND HIGH GRADE COMPONENTS EXTEND TO INKED MARGINS.

- TUMOR MEASURES 11 X 8 X 5.5 CM.

- 10% NECROSIS.

5) APPENDIX; APPENDECTOMY:

- APPENDIX WITH MUCOSAL NEUROMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	S-100	
	CHR	
	SYN	
	NF	
	CD117	
	NEG CONT	
	IMM RECUT	

Gross Description:

1.) The specimen is received fresh for frozen section, labeled "biopsy of retroperitoneal mass" and consists of a piece of myxoid tan tissue measuring 2.0 x 1.7 x 0.7 cm sectioning reveals myxoid homogeneous cut surfaces. A portion of tissue submitted for for possible future studies. A portion is submitted for frozen section and the remainder is submitted for permanent sections.

Summary of sections:

FSC - frozen section control

R - rest of specimen.

2). The specimen is received fresh, labeled "retroperitoneal sarcoma" and consists of a soft tissue mass resection specimen with two segments of intestine attached. The soft tissue mass measures 20 x 18 x 10 cm in greatest dimensions. Two surgical sutures are present on the specimen, which were surgically designated as: two stitches proximal small bowel, one

** Continued on next page **

[page 3 of 5]
LN - lymph nodes

4). The specimen is received fresh, labeled "retroperitoneal sarcoma" and consists of a soft tissue resection specimen measuring 11 x 8 x 5.5 cm in greatest dimensions. The specimen is not oriented. Surgical margins are inked in black. Sectioning of the specimen reveals a white to light yellow to tan variegated, soft to firm cut surface with approximately 5% of necrosis. Focal areas of hemorrhage are identified. Gross pictures are taken. Representative sections are submitted.

Summary of sections:

M surgical margins, perpendicular

RS representative sections of remaining tissue

5). The specimen is received in formalin, labeled "Appendix". It consist of a vermiform appendix measuring 5.7 cm length and 0.7 cm in diameter. There is attached yellow-tan fatty tissue measuring up to 2 cm in thickness. On cut section of the specimen, the lumen is grossly unremarkable and the wall of the appendix is uniform in thickness, measuring 0.4 cm. Representative sections are submitted.

Summary of sections:

DT-distal tip

APP-representative sections of appendix

Summary of Sections:

Part 1: SP: Biopsy of retroperitoneal mass

Block	Sect.	Site	PCs
1		FSC	1
1		R	1

Part 2: SP: Retroperitoneal sarcoma

Block	Sect.	Site	PCs
1		AM	1
1		CRRS	1
1		IM	1
1		LM	1
1		ORM	1
1		OSIM	1
1		PM	1
1		PRMS	1
1		PSIMS	1

** Continued on next page **

[page 4 of 5]
stitch proximal rectum. Further orientation is provided by the surgeon (Dr. . The proximal small bowel portion measures 32 cm in length and 4.5 cm in greatest circumference. The proximal rectum and colon portion measures 9 cm in length and 5 cm in greatest circumference. Surgical margins at the stitched areas on the two intestine portions are inked in blue, and the opposite surgical margins are inked in green. A portion of the soft tissue mass on the anterior surface of the specimen appears to have been surgically transected. This surface is now inked in blue. The remaining external surface of the soft tissue mass is inked in black.

Serial sectioning of the soft tissue mass reveals a light tan to light yellow variegated, fleshy to fibrotic cut surface with areas of hemorrhage and approximately 1% of necrosis. Grossly, the mass appears to attach to the serosal surface of the intestinal portions without invading their walls.

Opening of the intestinal portions reveals an unremarkable mucosal surface.

Samples of the soft tissue mass are submitted for Gross photos are taken. Representative sections are submitted.

Summary of sections:

TTS tumor at the transected area
AM anterior surgical margin, perpendicular
PM posterior surgical margin, perpendicular
SM superior surgical margin, perpendicular
IM inferior surgical margin, perpendicular
RM right surgical margin, perpendicular
LM left surgical margin, perpendicular
PSIMS proximal small intestine surgical margin at the two stitches area
OSIM opposite small intestine surgical margin
PRMS proximal rectal surgical margin at the one stitch area
ORM proximal colonic surgical margin opposite to the proximal rectal surgical margin
TSI tumor in relation to the adjacent small intestinal portion
TCR tumor in relation to the adjacent colonic/rectal portion
T additional sections of the tumor
SIRS representative sections of the small intestinal portion
CRRS representative sections of the colonic/rectal portion

3.) The specimen is received fresh, labeled "Left colon" and consists of an unoriented segment of colon that measures 19 cm in length with an average circumference of 3.5 cm. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 1.0 cm in thickness.

The serosal surface shows two 0.5 cm thin-walled cysts filled with clear fluid. No other lesions are identified. The specimen is opened to reveal no discrete lesion. The remaining mucosa is pink tan and folded with areas of focal hemorrhage and petechiae noted. A few lymph nodes are identified in the attached adipose tissue and are submitted. Representative sections of the specimen are submitted for permanent sections. Photographs are taken.

Summary of sections:

M1 - margin one
M2 - margin two
C - cysts
RC - representative sections of colon

** Continued on next page **

[page 5 of 5]
1	RM	1
1	SIRS	1
1	SM	1
15	T	15
1	TCR	1
1	TSI	1
1	TTS	1

Part 3: SP: Left colon

Block	Sect.	Site	PCs
1	C		1
1	LN		1
1	M1		1
1	M2		1
3	RC		3

Part 4: SP: Retroperitoneal sarcoma

Block	Sect.	Site	PCs
6	M		6
6	RS		6

Part 5: SP: Appendix

Block	Sect.	Site	PCs
1	app		1
1	dt		1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: HIGH GRADE SARCOMA.
PERMANENT DIAGNOSIS: SAME.

** End of Report **

hw 4/21/11

Source: NCI Genomic Data Commons file fb6a3ffd-5390-4559-b810-8f67fe9c1dae (TCGA-DX-A23Y.E3CB40E1-7F13-47B8-8F0B-AAC93EC6A63E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).